Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A51T, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A51T-06A (Metastatic).

[page 1 of 2]
***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) LEFT INGUINAL SENTINEL LYMPH NODE #1, NOT BLUE, COUNT 112, LYMPHADENECTOMY:
One lymph node. See addendum report.
- (B) LEFT INGUINAL SENTINEL LYMPH NODE #2, NOT BLUE, COUNT 73, LYMPHADENECTOMY:
One lymph node. See addendum report.
- (C) LEFT PARAMEDIAN BACK, SKIN ELLIPSE:
Skin and subcutaneous tissue with scar and biopsy site changes.
Margins of resection have been evaluated and are free of melanoma.
- (D) LEFT AXILLARY CONTENTS, LEVEL S I, II, III LYMPH NODES, LYMPHADENECTOMY:
METASTATIC MELANOMA TO ONE OF TWENTY-FIVE LYMPH NODES (1/25).
THE TUMOR MEASURES 40 X 25 MM (AS PER GROSS DESCRIPTION).
LOCATION: SUBCAPSULAR AND INTRAPARENCHYMAL
Final assessment for extracapsular extension is pending examination of additional sections; an addendum report will follow.
- (E) ADDITIONAL LEVEL III LYMPH NODES, LYMPHADENECTOMY:
Eighteen lymph nodes, no tumor is identified (0/18).

ICD-0-3
Melanoma, NOS 8720/3
Site: lymph node, axillary C77.3
lw
11/6/12

GROSS DESCRIPTION

- (A) LEFT INGUINAL SENTINEL LYMPH NODE #1, NOT BLUE, COUNT 112 - A 2.4 x 1.3 x 0.7 cm lymph node.
SECTION CODE: A1, A2, one possible lymph node serially sectioned. The entire specimen is submitted.
- (B) LEFT INGUINAL SENTINEL LYMPH NODE #2, NOT BLUE, COUNT 73 - A 0.8 x 0.7 x 0.5 cm lymph node.
SECTION CODE: B1, one possible lymph node serially sectioned. The entire specimen is submitted.
- (C) 2 CM MARGIN MELANOMA, LEFT PARAMEDIAN BACK, SHORT - SUPERIOR, LONG - LEFT LATERAL - A tan skin ellipse measuring 14.2 x 5.0 x 5.0 cm. The specimen is inked in its central portion but it also shows a 1.0 cm circular area that appears to be a 0.6 cm circular, elevated, healed scar. This central area is located at 6.5 cm from the superior (12 o'clock tip), at 1.7 cm from the 3 o'clock edge, 6.2 cm from the 6 o'clock tip and 1.8 cm from the 9 o'clock edge.
INK CODE: Blue - from 12-3-6 o'clock; orange- from 6-9-12 o'clock.
SECTION CODE: C1, 12 o'clock tip, ink side up; C2, 6 o'clock tip, ink side up; C3, 3 o'clock edge, ink side up; C4, 9 o'clock edge, ink side up; C5, deep margin related to the area of interest; C6-C13, area of interest from 12-6 o'clock.
- (D) LEFT AXILLARY CONTENTS, LEVEL 1, 2, 3 NODES - One pale-gray fibroadipose tissue (12.5 x 9.0 x 6.0 cm) with a pale-gray mass (4.0 x 3.5 x 2.5 cm) with a pale-gray cut surface with focal hemorrhage and possible central necrosis. Multiple lymph nodes are identified ranging from 0.3 x 0.3 x 0.3 cm to 4.0 x 2.5 x 1.5 cm. The lymph nodes are entirely submitted. The mass area is representatively submitted.
SECTION CODE: D1, mass with the hemorrhage; D2, mass with possible central necrosis; D3-D5, representative sections of other areas of the mass; D6-D8, each containing four possible lymph nodes; D9-D12, each containing two possible lymph nodes; D13, one possible lymph node serially sectioned; D14, D15, one possible lymph node serially sectioned; D16, D17, one lymph node serially sectioned; D18-D21, entirely submitted of the largest lymph node.
- (E) ADDITIONAL LEVEL 3 NODES - Two pale-gray fibroadipose tissue (5.0 x 4.0 x 2.0 cm in aggregate) with multiple possible lymph nodes ranging from 0.3 x 0.2 x 0.2 cm to 2.0 x 1.5 x 0.7 cm. The lymph nodes are entirely submitted.
SECTION CODE: E1, E2, each containing four possible lymph nodes; E3-E6, each containing two possible lymph nodes; E7, E8, each containing one possible lymph node serially sectioned; E9, E10, one possible lymph node serially sectioned.

CLINICAL HISTORY

None given.

SNOMED CODES

M-00110 M-00110 M-78060 M-87206 M-00110

Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

Entire report and diagnosis completed by:

These tests have not been

[page 2 of 2]
ADDENDUM

This modified report is being issued to provide additional information/results.

GROSS DESCRIPTION

(D) LEFT AXILLARY CONTENTS, LEVEL I, II, III NODE – The largest mass is entirely submitted.
SECTION CODE: D22-D33, entirely submitted of the remainder of the largest mass.

COMMENT

(A, B) Examination of additional tissue levels and an immunohistochemical study on paraffin sections with an anti-melanocytic cocktail (HMB45, anti-MART1 and anti-tyrosinase) fails to reveal metastatic melanoma.

(D) Additional sections of the lymph node involved by melanoma were examined and no definite extracapsular extension is identified in the cross-sections examined. Tumor necrosis is seen.

Entire report and diagnosis completed by:

-----END OF REPORT-----

Histology Discrepancy		☒

Source: NCI Genomic Data Commons file 459e5e95-e937-40e6-835d-652cc97b3fe8 (TCGA-D3-A51T.886880FB-23ED-44C6-8565-8FB26F51F4AB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).